Somatic mutation profile of tumor specimen TCGA-FF-8042-01A (aliquot TCGA-FF-8042-01A-11D-2210-10) from TCGA case TCGA-FF-8042, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 57.5 years (21,005 days).
Specimen TCGA-FF-8042-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f54e96d-9ed0-438d-a355-32baec35ab5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FF-8042-10A (Blood Derived Normal), aliquot TCGA-FF-8042-10A-01D-2210-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ea47e32-40dc-47ef-96d8-a1fbafb08580

The open-access MAF lists 290 somatic variants for this specimen: 214 protein-altering or splice-affecting, 58 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 193, Silent 58, Nonsense Mutation 10, Intron 7, 3'UTR 6, Frame Shift Del 6, Splice Site 2, RNA 2, 3'Flank 2, Frame Shift Ins 2, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARD11 | c.645G>C p.K215N | Missense Mutation (SNP) | VAF 151/277 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV62716912, COSV62718953; called by muse, mutect2, varscan2
- KMT2D | c.4168dup p.A1390Gfs*42 | Frame Shift Ins (INS) | VAF 17/52 reads (33%) | catalogued as rs756471180; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ALG10 | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 103/259 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.671); catalogued as rs1392426447; called by muse, mutect2, varscan2
- AMOT | c.2086C>G p.L696V (on ENST00000371959 / NM_001113490.1; = p.L287V on NM_133265.3) | Missense Mutation (SNP) | VAF 108/178 reads (61%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.936); catalogued as rs768585062; called by muse, mutect2, varscan2
- AMY2B | c.692A>T p.N231I | Missense Mutation (SNP) | VAF 102/253 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV63715875; called by muse, mutect2, varscan2
- APC | c.2203G>A p.A735T | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.253); catalogued as COSV57360335; called by muse, mutect2, varscan2
- ASXL1 | c.3121del p.A1041Pfs*6 | Frame Shift Del (DEL) | VAF 40/136 reads (29%) | catalogued as COSV60120367, COSV99045590; called by mutect2, pindel, varscan2
- ATP10D | c.4192T>G p.L1398V | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV56700032; called by muse, mutect2, varscan2
- ATP13A5 | c.1265A>G p.Y422C | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs771196726; called by muse, mutect2, varscan2
- BARHL2 | c.673C>G p.P225A | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs1173304742, COSV64980760; called by muse, mutect2, varscan2
- BMP5 | c.194C>A p.P65H | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63702685; called by muse, mutect2, varscan2
- CARD11 | c.101G>C p.S34T | Missense Mutation (SNP) | VAF 57/208 reads (27%) | SIFT tolerated (0.97); PolyPhen benign (0.015); catalogued as COSV100712215; called by muse, varscan2
- CASC3 | c.1978G>A p.V660I | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1358611032; called by muse, mutect2, varscan2
- CBX6 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1269154617, COSV53321122; called by muse, varscan2
- CDKL2 | c.1470A>C p.E490D | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.956); catalogued as COSV56735139; called by muse, mutect2, varscan2
- CHKA | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99694070, COSV99694128; called by muse, mutect2, varscan2
- CNTNAP4 | c.115T>G p.L39V | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1275855464; called by muse, mutect2, varscan2
- COL11A1 | c.2510T>C p.L837P | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100614690, COSV62175663, COSV62200150; called by muse, mutect2, varscan2
- CPAMD8 | c.3295G>A p.G1099S (on ENST00000651564; = p.G1052S on NM_015692.5) | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71595939; called by muse, mutect2, varscan2
- CYSLTR1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 58/83 reads (70%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV100964707, COSV64820985; called by muse, mutect2, varscan2
- DAGLA | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV57197364; called by muse, mutect2, varscan2
- DCHS1 | c.9146A>T p.E3049V | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368872716; called by muse, mutect2, varscan2
- DNAH1 | c.5480G>A p.R1827H | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs377201322; called by muse, mutect2, varscan2
- DPP10 | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100071628, COSV59694727; called by muse, mutect2, varscan2
- DSCAM | c.4859G>A p.R1620Q | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.788); catalogued as rs779560899; called by muse, mutect2, varscan2
- DSEL | c.1522A>C p.N508H | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100026148, COSV59490091; called by muse, mutect2, varscan2
- EPS8L2 | c.1816G>A p.A606T | Missense Mutation (SNP) | VAF 59/132 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100585749; called by muse, mutect2, varscan2
- ETS2 | c.1358C>T p.T453M | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.782); catalogued as rs997447535; called by muse, mutect2, varscan2
- FILIP1 | c.3460C>T p.R1154W | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs369386052, COSV52741820; called by muse, mutect2, varscan2
- FLNC | c.4945G>A p.G1649S | Missense Mutation (SNP) | VAF 64/233 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); catalogued as COSV57962577; called by muse, mutect2, varscan2
- FMNL2 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 76/257 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs377497365; called by muse, mutect2, varscan2
- FSD1 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs777263812, COSV55695505; called by muse, mutect2, varscan2
- GABRB1 | c.1142C>T p.S381L | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs539587921, COSV54996293; called by muse, mutect2, varscan2
- GPC6 | c.83G>T p.R28L | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as COSV100990247; called by muse, mutect2, varscan2
- GRIN2A | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.108); catalogued as rs796052542, COSV58028457, COSV58028652; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIN2B | c.3731C>T p.A1244V | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs772176416; called by muse, mutect2, varscan2
- H1-4 | c.311C>G p.S104C | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV56803422, COSV99175192; called by muse, mutect2, varscan2
- HPDL | c.665G>A p.G222D | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs761274996; called by muse, mutect2, varscan2
- HTT | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 86/210 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs1222187754, COSV61857634; called by muse, mutect2, varscan2
- IGHV4-34 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 166/396 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.109); catalogued as rs11546806; called by muse, mutect2, varscan2
- IRAK2 | c.425-1G>A p.X142_splice | Splice Site (SNP) | VAF 14/65 reads (22%) | catalogued as COSV99843680; called by muse, mutect2, varscan2
- KALRN | c.6436C>T p.R2146C (on ENST00000360013 / NM_001024660.4; = p.R449C on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs776077977, COSV52252244; called by muse, mutect2, varscan2
- KLF15 | c.832T>G p.F278V | Missense Mutation (SNP) | VAF 90/366 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99955329; called by muse, mutect2, varscan2
- KRT12 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as rs1484808067; called by muse, mutect2, varscan2
- LRFN5 | c.1025T>G p.L342R | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV53245388, COSV53273192; called by muse, mutect2, varscan2
- MAGEB16 | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 51/81 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs774566572, COSV104433685; called by muse, mutect2, varscan2
- MDGA2 | c.1327T>G p.F443V (on ENST00000399232 / NM_001113498.2; = p.F145V on NM_182830.4) | Missense Mutation (SNP) | VAF 51/215 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.281); catalogued as rs947772029, COSV62094082; called by muse, mutect2, varscan2
- MYF6 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1234740280, COSV57353681; called by muse, mutect2, varscan2
- NASP | c.1814C>T p.A605V | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as COSV59646178; called by muse, mutect2, varscan2
- NEDD4L | c.2717C>T p.S906L (on ENST00000400345 / NM_001144967.3; = p.S886L on NM_015277.6) | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56851728; called by muse, mutect2, varscan2
- NEFL | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs752545805, COSV55338613; called by muse, mutect2, varscan2
- NKAPL | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 45/79 reads (57%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV59199689; called by muse, mutect2, varscan2
- NR2E3 | c.97G>T p.G33C | Missense Mutation (SNP) | VAF 63/264 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV100489222; called by muse, mutect2, varscan2
- NTRK3 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.855); catalogued as COSV58124542, COSV58148859; called by muse, mutect2, varscan2
- OR2M2 | c.895A>G p.R299G | Missense Mutation (SNP) | VAF 88/128 reads (69%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100677182; called by muse, mutect2, varscan2
- OR51A2 | c.563A>C p.K188T | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100985007; called by muse, mutect2, varscan2
- OR51A4 | c.563A>C p.K188T | Missense Mutation (SNP) | VAF 141/625 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100985183; called by mutect2, varscan2
- OR52N5 | c.95A>C p.H32P | Missense Mutation (SNP) | VAF 72/189 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs756444266; called by muse, mutect2, varscan2
- OR5B21 | c.196C>T p.L66F | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.027); catalogued as rs1183481662; called by muse, mutect2, varscan2
- PAX4 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776151854, COSV100490333, COSV58387497; called by muse, mutect2, varscan2
- PAX5 | c.781-1G>A p.X261_splice | Splice Site (SNP) | VAF 14/28 reads (50%) | catalogued as COSV100814043; called by muse, mutect2, varscan2
- PCDH15 | c.4909T>C p.S1637P | Missense Mutation (SNP) | VAF 64/173 reads (37%) | SIFT tolerated, low confidence (0.13); catalogued as COSV64701065; called by muse, mutect2, varscan2
- PDE10A | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.149); catalogued as rs1403420962, COSV63091276; called by muse, mutect2, varscan2
- PKD1L1 | c.5837C>T p.P1946L | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99218067; called by muse, mutect2, varscan2
- PLCXD3 | c.784A>C p.S262R | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.944); catalogued as COSV60614936; called by muse, mutect2, varscan2
- PLK2 | c.1004del p.L335Cfs*68 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as rs772701630; called by mutect2, varscan2
- RAF1 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as CM122807, COSV50103883; called by muse, mutect2, varscan2
- RITA1 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.199); catalogued as rs368110690; called by muse, mutect2, varscan2
- ROBO3 | c.770G>T p.R257L | Missense Mutation (SNP) | VAF 65/129 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67299213, COSV67301332; called by muse, mutect2, varscan2
- SAMHD1 | c.600G>T p.Q200H | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV53430859; called by muse, mutect2, varscan2
- SCRIB | c.2717C>T p.A906V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as rs782178893, COSV100253201; called by muse, mutect2
- SEMA4B | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs779317447, COSV60172746; called by muse, mutect2, varscan2
- SLC47A1 | c.1156C>T p.H386Y | Missense Mutation (SNP) | VAF 71/184 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs547527862; called by muse, mutect2, varscan2
- SNTB1 | c.110T>G p.V37G | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101179768; called by muse, mutect2
- SPHKAP | c.2807C>T p.T936M | Missense Mutation (SNP) | VAF 64/151 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as rs750731787, COSV60891891; called by muse, mutect2, varscan2
- STYXL2 | c.3109C>T p.P1037S | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99608881; called by muse, mutect2, varscan2
- TEX10 | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as rs1199690326; called by muse, mutect2, varscan2
- TMC1 | c.373A>C p.K125Q | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs377607548; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM201 | c.1475C>T p.S492F | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.659); catalogued as COSV61161340; called by muse, mutect2, varscan2
- TNK2 | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 43/197 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs761815054, COSV57373699; called by muse, mutect2, varscan2
- TRAK1 | c.2240G>A p.R747Q | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.522); catalogued as rs537037086, COSV100565789; called by muse, mutect2, varscan2
- TRPM3 | c.449G>A p.G150D (on ENST00000357533 / NM_001366142.2; = p.G119D on NM_001007471.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/196 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.082); catalogued as rs1041299007; called by muse, mutect2, varscan2
- TTN | c.65077G>C p.E21693Q (on ENST00000591111; = p.E14269Q on NM_003319.4) | Missense Mutation (SNP) | VAF 33/89 reads (37%) | PolyPhen possibly damaging (0.776); catalogued as rs1355358331; called by muse, mutect2, varscan2
- UNC13C | c.5101G>C p.E1701Q | Missense Mutation (SNP) | VAF 69/193 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs768039530, COSV52841291, COSV52849785; called by muse, mutect2, varscan2
- VCAN | c.6095A>C p.K2032T | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs1416467538, COSV54105198; called by muse, mutect2, varscan2
- VWDE | c.3415A>C p.S1139R | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV51723681; called by muse, mutect2, varscan2
- YIPF7 | c.82T>G p.L28V | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as COSV60657676; called by muse, mutect2, varscan2
- ZBTB20 | c.1795G>A p.V599I (on ENST00000474710 / NM_001164342.2; = p.V526I on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/303 reads (27%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.984); catalogued as rs1331926530; called by muse, mutect2, varscan2
- ZMYM3 | c.3802G>A p.D1268N | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV58738690, COSV58741480; called by muse, mutect2, varscan2
- ZNF443 | c.340G>A p.G114S | Missense Mutation (SNP) | VAF 86/192 reads (45%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.881); catalogued as COSV56893822; called by muse, mutect2, varscan2
- ZSWIM4 | c.637A>C p.T213P | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs199644245; called by muse, mutect2, varscan2
- AADACL3 | c.1138C>T p.L380F | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- AATF | c.107T>C p.V36A | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ACOX1 | c.1450A>C p.T484P | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- ADAMTS9 | c.4775G>T p.G1592V | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADCY2 | c.1460A>C p.K487T | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- AFDN | c.5315C>T p.S1772F (on ENST00000447894 / NM_001366320.1; = p.S1691F on NM_001207008.1) | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- AGBL1 | c.2693G>T p.C898F | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ANKRD30B | c.1728T>A p.D576E | Missense Mutation (SNP) | VAF 72/446 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ARL6IP4 | c.652A>G p.R218G | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARPP21 | c.955A>T p.N319Y | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- ARSF | c.1105G>A p.G369R | Missense Mutation (SNP) | VAF 67/101 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BIRC2 | c.1492C>G p.Q498E | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- BRWD3 | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 78/115 reads (68%) | called by muse, mutect2, varscan2
- C11orf86 | c.239G>C p.R80P | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CAVIN2 | c.1051A>C p.I351L | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCR3 | c.866T>G p.I289S | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CCT6A | c.1362C>G p.N454K | Missense Mutation (SNP) | VAF 64/274 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- CDH20 | c.480C>A p.D160E | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CHD4 | c.2311C>G p.L771V (on ENST00000357008 / NM_001363606.2; = p.L784V on NM_001273.5) | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CHST11 | c.428A>C p.K143T | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- CNOT3 | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL5A2 | c.1871G>A p.G624D | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL8A1 | c.1258G>A p.G420R | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSDE1 | c.601G>T p.E201* (on ENST00000358528 / NM_001007553.3; = p.E170* on NM_007158.6) | Nonsense Mutation (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- CSNK2A1 | c.794T>G p.L265* | Nonsense Mutation (SNP) | VAF 49/99 reads (49%) | called by muse, mutect2, varscan2
- DCHS1 | c.7078G>A p.A2360T | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DLX6 | c.863A>C p.Q288P | Missense Mutation (SNP) | VAF 38/179 reads (21%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- DMP1 | c.165A>C p.K55N | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- DPYS | c.1243T>G p.S415A | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ENOX1 | c.50T>C p.L17P | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBLN1 | c.1826T>C p.F609S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- FBN1 | c.8593A>C p.K2865Q | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- FBXO15 | c.1189A>T p.N397Y | Missense Mutation (SNP) | VAF 28/173 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- FLG | c.3025C>G p.H1009D | Missense Mutation (SNP) | VAF 116/321 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- G2E3 | c.561T>G p.F187L | Missense Mutation (SNP) | VAF 55/187 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- GABRG3 | c.1250T>G p.F417C | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- GALNT1 | c.1529C>T p.P510L | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GGNBP2 | c.199G>T p.D67Y | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- GPCPD1 | c.569T>G p.L190* | Nonsense Mutation (SNP) | VAF 63/141 reads (45%) | called by muse, mutect2, varscan2
- GRID1 | c.1029G>A p.W343* | Nonsense Mutation (SNP) | VAF 53/125 reads (42%) | called by muse, mutect2, varscan2
- GRM7 | c.1471G>C p.G491R | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- GULP1 | c.302G>A p.C101Y | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- H2AC6 | c.115_127del p.N39Gfs*14 | Frame Shift Del (DEL) | VAF 38/196 reads (19%) | called by mutect2, pindel, varscan2
- HCN4 | c.2230C>A p.Q744K | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, mutect2
- HELZ | c.569A>G p.Q190R | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- HMGCR | c.2268T>G p.I756M | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- IGKJ2 | chr2:88861553 del AAAACTGCACACACAATGGTTCCTCTT | Missense Mutation (DEL) | VAF 52/174 reads (30%) | called by mutect2, pindel
- IGKV2D-30 | c.208A>T p.R70W | Missense Mutation (SNP) | VAF 132/383 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- IKZF2 | c.901A>G p.M301V | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- INPP4B | c.2498A>C p.K833T | Missense Mutation (SNP) | VAF 90/214 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- JPT1 | c.461G>A p.G154D | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNA6 | c.751_754del p.L251Vfs*45 | Frame Shift Del (DEL) | VAF 43/109 reads (39%) | called by pindel, varscan2
- KCNK18 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- KLHL14 | c.1681A>C p.S561R | Missense Mutation (SNP) | VAF 52/254 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KMT2D | c.16427C>A p.S5476Y | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KMT2D | c.16425T>A p.H5475Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LARP1 | c.1699T>C p.S567P (on ENST00000518297 / NM_033551.3; = p.S490P on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/53 reads (81%) | SIFT tolerated (0.11); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- LINGO1 | c.1540G>C p.V514L | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- LRRFIP1 | c.1891G>A p.A631T | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- MARCHF7 | c.173C>G p.S58C | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MCM3AP | c.478dup p.A160Gfs*2 | Frame Shift Ins (INS) | VAF 17/41 reads (41%) | called by mutect2, pindel, varscan2
- MEX3A | c.628T>C p.S210P | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.221); called by muse, mutect2
- MIPEP | c.1039A>G p.N347D | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- MKRN2 | c.62A>G p.Q21R | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- MPP7 | c.606A>G p.I202M | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.924); called by muse, varscan2
- MSN | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 51/73 reads (70%) | called by muse, mutect2, varscan2
- NDUFS1 | c.394G>C p.D132H | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- NFIB | c.535T>G p.F179V | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- NRXN3 | c.1421A>G p.D474G (on ENST00000335750 / NM_001330195.2; = p.D101G on NM_004796.6) | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NXF1 | c.1146C>G p.N382K | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OCRL | c.1640T>G p.F547C | Missense Mutation (SNP) | VAF 80/98 reads (82%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- OR4C46 | c.727A>G p.T243A | Missense Mutation (SNP) | VAF 71/184 reads (39%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- OTOP1 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- P2RY8 | c.601C>G p.L201V | Missense Mutation (SNP) | VAF 33/45 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- PCDHB10 | c.2256G>T p.Q752H | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PEAR1 | c.2456A>T p.N819I | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PGBD4 | c.1383C>A p.H461Q | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEKHM3 | c.1782C>A p.H594Q | Missense Mutation (SNP) | VAF 61/139 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- PPARG | c.1317C>A p.D439E (on ENST00000287820 / NM_015869.5; = p.D409E on NM_005037.7) | Missense Mutation (SNP) | VAF 57/268 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PREX2 | c.1193A>G p.D398G | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PRMT9 | c.2209C>G p.R737G | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- PROX1 | c.1734A>C p.E578D | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- PRRT4 | c.1018C>G p.P340A | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, varscan2
- PTPN21 | c.1010A>G p.Y337C | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PTPN4 | c.2581G>A p.V861I | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- RAB29 | c.108C>G p.Y36* | Nonsense Mutation (SNP) | VAF 33/90 reads (37%) | called by muse, mutect2, varscan2
- RAI1 | c.2836_2837del p.L946Vfs*7 | Frame Shift Del (DEL) | VAF 51/137 reads (37%) | called by pindel, varscan2
- RALGAPA1 | c.670A>T p.S224C | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RGS6 | c.1078T>C p.S360P | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- RIMBP2 | c.1171G>A p.V391M | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- RNF133 | c.716T>G p.L239R | Missense Mutation (SNP) | VAF 83/422 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SDHAF2 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 74/164 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- SEMA3E | c.1901A>C p.K634T | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- SEMA5A | c.2120C>A p.T707N | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT tolerated (0.72); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SEPTIN6 | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 31/48 reads (65%) | called by muse, mutect2, varscan2
- SERPINB2 | c.187G>T p.V63L | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SERPINH1 | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2
- SH3TC1 | c.1192C>T p.Q398* | Nonsense Mutation (SNP) | VAF 42/89 reads (47%) | called by muse, mutect2, varscan2
- SLAMF6 | c.415A>G p.S139G | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- SLC1A7 | c.580C>A p.H194N | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, varscan2
- SLC1A7 | c.575G>A p.G192D | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, varscan2
- SLC22A23 | c.1712G>A p.G571E | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC4A7 | c.3563G>T p.S1188I | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SORCS3 | c.1414A>C p.T472P | Missense Mutation (SNP) | VAF 80/184 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SYCP1 | c.2120T>G p.I707R | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYNJ2 | c.2955G>A p.M985I | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAAR2 | c.364T>G p.F122V (on ENST00000367931 / NM_001033080.1; = p.F77V on NM_014626.3) | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBC1D23 | c.1971G>C p.K657N (on ENST00000394144 / NM_001199198.3; = p.K642N on NM_018309.5) | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- TDRD15 | c.434A>C p.K145T | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- THOC7 | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 66/244 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- THRB | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- THSD7A | c.2258C>A p.P753H | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TMSB4X | c.27G>C p.E9D | Missense Mutation (SNP) | VAF 133/199 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- TOGARAM2 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- TRDN | c.995A>G p.K332R | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TRIO | c.2253C>G p.N751K | Missense Mutation (SNP) | VAF 142/348 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- TRPM6 | c.102A>C p.K34N | Missense Mutation (SNP) | VAF 43/69 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- TTN | c.77703_77706del p.F25901Lfs*37 (on ENST00000591111; = p.F18477Lfs*37 on NM_003319.4) | Frame Shift Del (DEL) | VAF 44/104 reads (42%) | called by mutect2, pindel, varscan2
- UNC5B | c.1927C>T p.Q643* | Nonsense Mutation (SNP) | VAF 23/45 reads (51%) | called by muse, mutect2, varscan2
- VPS8 | c.2048T>C p.I683T (on ENST00000625842 / NM_001349294.1; = p.I681T on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/228 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- ZNF436 | c.494C>A p.P165H | Missense Mutation (SNP) | VAF 82/208 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF461 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- ZNF521 | c.3846A>C p.E1282D | Missense Mutation (SNP) | VAF 63/430 reads (15%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- A2ML1 | c.2607T>C p.T869= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs749529764; called by muse, mutect2, varscan2
- AHNAK2 | c.2820C>G p.G940= | Silent (SNP) | VAF 62/170 reads (36%) | called by muse, mutect2, varscan2
- ALDH1L1 | c.291C>T p.A97= | Silent (SNP) | VAF 43/152 reads (28%) | catalogued as rs747640087; called by muse, mutect2, varscan2
- ALG12 | c.384C>G p.T128= | Silent (SNP) | VAF 43/145 reads (30%) | called by muse, mutect2, varscan2
- ANKRD29 | c.690G>A p.L230= | Silent (SNP) | VAF 24/162 reads (15%) | called by muse, mutect2, varscan2
- ANTXR2 | c.1302A>G p.K434= | Silent (SNP) | VAF 98/273 reads (36%) | called by muse, mutect2, varscan2
- ARHGEF5 | c.1350T>C p.S450= | Silent (SNP) | VAF 46/230 reads (20%) | catalogued as COSV99282562; called by muse, mutect2, varscan2
- BSN | c.5760C>T p.A1920= | Silent (SNP) | VAF 61/237 reads (26%) | catalogued as rs185582385; called by muse, mutect2, varscan2
- CCDC102B | c.1479G>A p.L493= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs751886467, COSV60143892; called by muse, mutect2, varscan2
- CFAP100 | c.1113G>A p.E371= | Silent (SNP) | VAF 39/134 reads (29%) | catalogued as rs1385951550; called by muse, mutect2, varscan2
- CSNK1G3 | c.138A>G p.G46= | Silent (SNP) | VAF 30/126 reads (24%) | catalogued as COSV62054115, COSV62057434; called by muse, varscan2
- DCC | c.600C>T p.S200= | Silent (SNP) | VAF 33/191 reads (17%) | catalogued as rs767578049; called by muse, mutect2, varscan2
- DNAI2 | c.657C>T p.L219= | Silent (SNP) | VAF 47/98 reads (48%) | catalogued as rs539461253; called by muse, mutect2, varscan2
- DNM3 | c.1260G>A p.L420= | Silent (SNP) | VAF 39/102 reads (38%) | called by muse, mutect2, varscan2
- DPYSL5 | c.1050C>T p.G350= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as rs772609424, COSV56509721; called by muse, mutect2, varscan2
- DRP2 | c.933C>T p.S311= | Silent (SNP) | VAF 49/65 reads (75%) | called by muse, mutect2, varscan2
- EPHB3 | c.699G>A p.S233= | Silent (SNP) | VAF 43/130 reads (33%) | catalogued as rs769299714; called by muse, mutect2, varscan2
- EYA4 | c.1596A>G p.L532= (on ENST00000531901 / NM_001301013.1; = p.L526= on NM_004100.5) | Silent (SNP) | VAF 19/87 reads (22%) | called by muse, mutect2, varscan2
- FAT4 | c.1752G>A p.Q584= | Silent (SNP) | VAF 32/75 reads (43%) | called by muse, mutect2, varscan2
- FGF3 | c.492C>G p.R164= | Silent (SNP) | VAF 48/127 reads (38%) | called by muse, mutect2, varscan2
- GPC6 | c.84G>T p.R28= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV65498123; called by muse, mutect2, varscan2
- H4C11 | c.171G>A p.G57= | Silent (SNP) | VAF 50/228 reads (22%) | catalogued as rs780788014, COSV100747934; called by muse, mutect2, varscan2
- HERC5 | c.3048C>T p.A1016= | Silent (SNP) | VAF 64/159 reads (40%) | catalogued as rs756694449, COSV99987885; called by muse, mutect2, varscan2
- HMCN2 | c.174C>T p.G58= | Silent (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- HUNK | c.1884C>T p.N628= | Silent (SNP) | VAF 30/90 reads (33%) | called by muse, mutect2, varscan2
- LAMA5 | c.10653C>T p.P3551= | Silent (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- LRP1B | c.12534T>C p.D4178= | Silent (SNP) | VAF 52/122 reads (43%) | called by muse, mutect2, varscan2
- MYADM | c.453C>T p.Y151= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as rs376434685; called by muse, mutect2, varscan2
- OR2M3 | c.450C>T p.I150= | Silent (SNP) | VAF 111/173 reads (64%) | catalogued as COSV101513421; called by muse, mutect2, varscan2
- OR2S2 | c.867C>A p.T289= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as COSV59531020; called by muse, mutect2, varscan2
- OR5T1 | c.600T>G p.S200= | Silent (SNP) | VAF 106/295 reads (36%) | catalogued as COSV100478902, COSV57301674, COSV57301917; called by muse, mutect2, varscan2
- OVCH1 | c.2622T>C p.S874= | Silent (SNP) | VAF 33/121 reads (27%) | called by muse, mutect2
- PARD3B | c.2148T>C p.D716= | Silent (SNP) | VAF 55/153 reads (36%) | called by muse, mutect2, varscan2
- PCDHA13 | c.2193G>A p.A731= | Silent (SNP) | VAF 73/94 reads (78%) | catalogued as COSV56482171, COSV99166516; called by muse, mutect2, varscan2
- PCDHGB2 | c.1332C>T p.D444= | Silent (SNP) | VAF 89/139 reads (64%) | catalogued as rs1431516547, COSV53935326; called by muse, mutect2, varscan2
- PGPEP1L | c.459G>A p.G153= | Silent (SNP) | VAF 44/170 reads (26%) | called by muse, mutect2, varscan2
- PHRF1 | c.3090G>A p.S1030= (on ENST00000264555 / NM_001286581.2; = p.S1029= on NM_020901.4) | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as rs780096436, COSV99199329; called by muse, mutect2, varscan2
- PIDD1 | c.1749G>A p.Q583= | Silent (SNP) | VAF 54/127 reads (43%) | catalogued as rs1283317336; called by muse, mutect2, varscan2
- PITPNM3 | c.2088C>G p.R696= | Silent (SNP) | VAF 24/70 reads (34%) | called by muse, mutect2, varscan2
- PRDM10 | c.1294C>T p.L432= | Silent (SNP) | VAF 41/140 reads (29%) | called by muse, mutect2, varscan2
- PRDX5 | c.15C>G p.G5= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as rs202108463; called by muse, varscan2
- PYGL | c.1944C>T p.N648= | Silent (SNP) | VAF 52/202 reads (26%) | catalogued as COSV53585788; called by muse, mutect2, varscan2
- RETSAT | c.591G>T p.L197= | Silent (SNP) | VAF 42/114 reads (37%) | called by muse, mutect2, varscan2
- ROBO1 | c.3972G>A p.T1324= | Silent (SNP) | VAF 54/187 reads (29%) | catalogued as rs774991528; called by muse, mutect2, varscan2
- RYR2 | c.841A>C p.R281= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV63674295; called by muse, mutect2, varscan2
- SACS | c.9210T>C p.V3070= | Silent (SNP) | VAF 42/112 reads (38%) | called by muse, mutect2, varscan2
- SHANK2 | c.870T>G p.T290= | Silent (SNP) | VAF 38/111 reads (34%) | called by muse, mutect2, varscan2
- SLC44A2 | c.1728G>A p.S576= | Silent (SNP) | VAF 110/223 reads (49%) | catalogued as rs1263153727, COSV100213550; called by muse, mutect2, varscan2
- SNRK | c.348C>T p.A116= | Silent (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- SUPT5H | c.264C>T p.D88= | Silent (SNP) | VAF 68/166 reads (41%) | catalogued as rs752398773, COSV100782163; called by muse, mutect2, varscan2
- TCP1 | c.241C>T p.L81= | Silent (SNP) | VAF 114/419 reads (27%) | called by muse, mutect2, varscan2
- THBS2 | c.1776C>T p.D592= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as rs148676859; called by muse, mutect2, varscan2
- TMPRSS12 | c.345G>A p.R115= | Silent (SNP) | VAF 39/83 reads (47%) | catalogued as rs374807523; called by muse, mutect2, varscan2
- TREH | c.21G>A p.E7= | Silent (SNP) | VAF 21/160 reads (13%) | called by muse, mutect2, varscan2
- TRIM58 | c.924C>T p.A308= | Silent (SNP) | VAF 38/54 reads (70%) | catalogued as rs775876778, COSV100825096, COSV63569313; called by muse, mutect2, varscan2
- TTC21A | c.2745C>A p.V915= | Silent (SNP) | VAF 32/101 reads (32%) | called by muse, mutect2, varscan2
- ZNF462 | c.3780G>T p.T1260= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV52934059; called by muse, mutect2, varscan2
- ZYX | c.1398C>T p.H466= | Silent (SNP) | VAF 32/68 reads (47%) | called by muse, varscan2
- ARL4A | chr7:12690866 A>G | 3'Flank (SNP) | VAF 15/43 reads (35%) | catalogued as COSV100775883; called by muse, mutect2, varscan2
- CCR2 | c.942-461T>C | Intron (SNP) | VAF 34/139 reads (24%) | catalogued as COSV99432017; called by muse, mutect2, varscan2
- DCHS2 | n.6226C>T | RNA (SNP) | VAF 49/124 reads (40%) | catalogued as COSV61777159; called by muse, mutect2, varscan2
- GEMIN7 | c.*630C>T | 3'UTR (SNP) | VAF 9/24 reads (38%) | catalogued as rs1250879201, COSV99541520; called by muse, mutect2, varscan2
- HNF4G | c.-23-3795A>C | Intron (SNP) | VAF 30/82 reads (37%) | catalogued as COSV62971987; called by muse, mutect2, varscan2
- IGLL5 | chr22:22901084 C>T | 3'Flank (SNP) | VAF 143/837 reads (17%) | catalogued as rs756295531; called by mutect2, varscan2
- IL1RAPL2 | c.698-78284A>C | Intron (SNP) | VAF 64/88 reads (73%) | called by muse, mutect2, varscan2
- MAGEC3 | c.1728+53C>A | Intron (SNP) | VAF 134/160 reads (84%) | called by muse, mutect2, varscan2
- MICAL3 | c.-75+43346G>A | Intron (SNP) | VAF 29/55 reads (53%) | catalogued as COSV99259965; called by muse, mutect2, varscan2
- MIR600 | chr9:123114585 G>T | 5'Flank (SNP) | VAF 41/92 reads (45%) | catalogued as rs1158275624; called by muse, mutect2, varscan2
- MUC19 | n.5653C>A | RNA (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- NBPF12 | c.*1G>A | 3'UTR (SNP) | VAF 8/50 reads (16%) | catalogued as rs1426069001; called by muse, mutect2
- OPRM1 | c.1165-11109T>G | Intron (SNP) | VAF 18/65 reads (28%) | catalogued as COSV100385038; called by muse, mutect2, varscan2
- SERTM1 | c.*2250G>A | 3'UTR (SNP) | VAF 25/58 reads (43%) | catalogued as rs776362037, COSV100171239; called by muse, mutect2, varscan2
- SPRY3 | c.*6473G>A | 3'UTR (SNP) | VAF 101/136 reads (74%) | catalogued as COSV100249177; called by muse, mutect2, varscan2
- SPTBN4 | c.5915+93G>A | Intron (SNP) | VAF 39/90 reads (43%) | called by muse, mutect2, varscan2
- SSTR1 | c.*568G>A | 3'UTR (SNP) | VAF 21/87 reads (24%) | catalogued as COSV99942710; called by muse, mutect2, varscan2
- ZNF501 | c.*612T>G | 3'UTR (SNP) | VAF 21/63 reads (33%) | catalogued as COSV101247050; called by muse, mutect2, varscan2
